Gene-level copy-number profile of tumor specimen TCGA-FD-A43P-01A from TCGA case TCGA-FD-A43P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.5 years (27,201 days).
Specimen TCGA-FD-A43P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3bfb2390-ff07-4d71-9cdc-3310c19f96e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A43P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6edbd7d-7d54-4a88-b509-03f6630d1b00

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 401; copy number 2: 7,784; copy number 3: 24,592; copy number 4: 9,926; copy number 5: 8,120; copy number 6: 5,296; copy number 7: 1,133; copy number 8: 442; copy number 9: 511; copy number 10: 213; copy number 11: 509; copy number 12: 298; copy number 13: 151; copy number 14: 32; copy number 15: 33; copy number 16: 11; copy number 18: 43; copy number 19: 62; copy number 21: 53; copy number 22: 4; copy number 23: 36; copy number 25: 53; copy number 26: 16; copy number 29: 37; copy number 30: 9; copy number 31: 15; copy number 52: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A43P-01A-31D-A23T-01): tumor purity 0.42, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,687 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,813,225–154,870,281, 287 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr1:159,171,609–163,769,691, 177 genes, copy number 7–10 (broad region; genes not listed).
- chr2:97,756,333–97,995,948, 1 gene, copy number 8 (within-gene range 6–8): TMEM131.
- chr2:97,913,054–103,176,260, 90 genes, copy number 8–9 (broad region; genes not listed).
- chr2:106,801,600–108,388,989, 30 genes, copy number 9 (within-gene range 5–9): ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886, AC064869.1, GACAT1, RGPD4-AS1, RGPD4, AC009963.2, AC009963.1, RPL22P8, SRSF3P5, SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4.
- chr3:857,124–15,722,311, 238 genes, copy number 10–25 (broad region; genes not listed).
- chr3:15,697,298–15,733,470, 3 genes, copy number 25: MIR3134, AC090950.2, AC090950.1.
- chr3:87,594,838–90,030,495, 22 genes, copy number 7–12: APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.
- chr3:184,778,723–198,222,513, 301 genes, copy number 7 (broad region; genes not listed).
- chr5:13,690,331–20,575,873, 103 genes, copy number 7–19 (within-gene range 4–19) (broad region; genes not listed).
- chr5:21,750,673–25,350,073, 41 genes, copy number 13–29 (within-gene range 5–29): CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2.
- chr6:15,934,782–23,404,132, 93 genes, copy number 11–31 (broad region; genes not listed).
- chr6:46,492,052–47,042,350, 12 genes, copy number 15: AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr6:105,904,373–107,133,170, 25 genes, copy number 52: RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–107,192,573, 1 gene, copy number 52: AL591516.1.
- chr10:44,712–744,958, 14 genes, copy number 25: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1.
- chr10:5,393,101–11,336,675, 96 genes, copy number 7–29 (broad region; genes not listed).
- chr11:50,409,042–57,819,546, 174 genes, copy number 7 (broad region; genes not listed).
- chr13:28,820,348–34,263,090, 88 genes, copy number 8–21 (within-gene range 5–21) (broad region; genes not listed).
- chr13:109,785,831–114,337,626, 111 genes, copy number 9 (broad region; genes not listed).
- chr15:29,609,676–30,355,540, 28 genes, copy number 8: AC102941.1, TUBBP8, AC102941.2, AC022613.1, TJP1, AC022613.3, HMGN2P5, AC022613.2, NCAPGP2, AC111152.2, SYNGR2P1, AC111152.1, GOLGA8J, RN7SL673P, DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA.
- chr17:29,071,122–29,180,398, 1 gene, copy number 8 (within-gene range 6–8): MYO18A.
- chr17:29,140,483–32,881,070, 175 genes, copy number 8 (broad region; genes not listed).
- chr17:36,936,785–38,605,952, 47 genes, copy number 9: LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1.
- chr17:60,443,158–62,320,189, 43 genes, copy number 7 (within-gene range 3–7): APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P, BCAS3, RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2, BRIP1, INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1, AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1.
- chr17:65,528,563–67,245,989, 25 genes, copy number 15–26 (within-gene range 3–26): AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH, RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48.
- chr17:69,577,251–69,903,000, 1 gene, copy number 18 (within-gene range 3–18): LINC01483.
- chr17:69,961,568–70,368,916, 9 genes, copy number 18: LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1.
- chr17:72,290,091–72,640,472, 1 gene, copy number 7 (within-gene range 4–7): LINC00511.
- chr17:72,627,231–78,632,155, 242 genes, copy number 7–11 (broad region; genes not listed).
- chr17:82,735,615–83,095,122, 9 genes, copy number 8 (within-gene range 3–8): FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL.
- chr19:30,850,975–46,196,218, 720 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr20:37,676,889–51,768,390, 347 genes, copy number 7–13 (within-gene range 3–13) (broad region; genes not listed).
- chr22:24,703,348–25,564,719, 31 genes, copy number 7: AP000358.1, CRIP1P4, PIWIL3, SGSM1, AL049759.1, TMEM211, KIAA1671, AL022323.2, AL022323.4, AL022323.1, AL022323.3, KIAA1671-AS1, Z99916.2, CRYBB3, Z99916.1, CRYBB2, Z99916.3, AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1.
- chr22:29,883,169–32,113,029, 101 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
